Somatic mutation profile of tumor specimen C3L-06087-60 (aliquot CPT0356660002) from CPTAC case C3L-06087, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 68.0 years (24,850 days).
Specimen C3L-06087-60: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3afbaf4-b60f-437c-b478-ee4a7f43207d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06087-50 (Buccal Cell Normal), aliquot CPT0356700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ad508ea-4363-4a83-a12e-4e5d02232f5b

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 2, Frame Shift Ins 1, Translation Start Site 1, In Frame Ins 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 73/182 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SRSF2 | c.284_307del p.P95_R102del | In Frame Del (DEL) | VAF 81/196 reads (41%) | hotspot (GDC flag); catalogued as rs766200080; called by mutect2, pindel
- CASKIN1 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs746279188, COSV58872638; called by muse, mutect2
- GCDH | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 226/479 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.262); catalogued as rs770100685, COSV99535894; called by muse, mutect2, varscan2
- GPR143 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs751622915, COSV66632596; called by muse, varscan2
- UNC13B | c.3350A>G p.N1117S | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs370999495; called by muse, mutect2, varscan2
- GABRA5 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.309); called by muse, varscan2
- GALR2 | c.1066C>G p.P356A | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- LY75 | c.4884dup p.K1629* | Frame Shift Ins (INS) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- NAA20 | c.103T>C p.Y35H | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OXR1 | c.1765_1766insTCA p.H589delinsLN (on ENST00000442977 / NM_001198532.1; = p.H588delinsLN on NM_018002.3) | In Frame Ins (INS) | VAF 20/43 reads (47%) | called by mutect2, pindel, varscan2
- PKD1L1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 78/160 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SEC14L4 | c.920T>A p.F307Y | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TRABD2B | c.674T>G p.F225C | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZFPM1 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 160/371 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GALNT9 | c.1077+351G>T | Intron (SNP) | VAF 43/88 reads (49%) | called by muse, mutect2, varscan2
- SMIM7 | c.*22A>T | 3'UTR (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- TEKT2 | c.283-64G>A | Intron (SNP) | VAF 86/166 reads (52%) | called by muse, mutect2, varscan2
